Surgical pathology report (de-identified scan), TCGA case TCGA-ZJ-A8QO, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site NCI HRE Branch, specimen TCGA-ZJ-A8QO-01A (Primary Tumor).

Pathology Department

ACCT#:

DOB:

ID:

Specimen #:

Date Obtained:

Date Received:

Dr:

Date Printed:

CLINICAL HISTORY:

CLINICAL HISTORY NOT SUBMITTED

ICD-0-3
carcinoma, squamous cell, large cell
non-keratinizing 8072/3

SPECIMEN/PROCEDURE:

1. CERVIX - CERVIX BIOPSY

Site: Cervix, NOS C53.9

hw
6/2/14

IMPRESSION:

CERVICAL BIOPSY:

Squamous cell carcinoma with stromal invasion, large cell non-keratinizing.

Dictated by:

Entered:

GROSS DESCRIPTION:

This case is part of the study.

Received in formalin, labeled with the patient's name, are five irregular portions of pink-tan to red-tan glistening and friable tissue, ranging from 0.4 x 0.4 x 0.2 cm to 0.7 x 0.5 x 0.2 cm. The largest portion of tissue is bisected. The specimen is entirely submitted in one cassette.

Dictated by:

Entered:

CPT Codes:

CERVICAL BIOPSY (1)/88305

ICD9 Codes:

180.9

Electronically Signed by:

Patient:

Age/Sex:

Acct#

I-PAA Discrepancy		✓

Source: NCI Genomic Data Commons file f9ffb999-cae4-42be-9ded-102089d47e3f (TCGA-ZJ-A8QO.F1113E49-016E-4D32-86C3-2620C9839F2E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).